Gene-level copy-number profile of tumor specimen HTMCP-03-06-02003-01B from CGCI case HTMCP-03-06-02003, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2.
Specimen HTMCP-03-06-02003-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc304249-7be1-4035-800a-ade9b2b5fc67.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02003-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/7031a477-6be4-406c-bda9-307e975810bb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 680; copy number 2: 13,366; copy number 3: 19,575; copy number 4: 18,749; copy number 5: 3,233; copy number 6: 2,142; copy number 7: 111; copy number 9: 173; copy number 10: 185; copy number 11: 25; copy number 12: 1; copy number 18: 1; copy number 19: 90; copy number 27: 5; copy number 32: 28.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:109,637,468–109,638,128, 1 gene: AP003102.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 619 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–205,022,822, 43 genes, copy number 7: ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1.
- chr7:38,239,580–38,340,998, 16 genes, copy number 9: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 9 (within-gene range 4–9): TRGV5P, TRGV5.
- chr11:34,049,967–36,232,136, 39 genes, copy number 9–11: AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1.
- chr11:60,835,996–61,161,615, 18 genes, copy number 7: AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1.
- chr11:85,628,573–107,018,476, 363 genes, copy number 9–27 (broad region; genes not listed).
- chr14:18,333,726–18,412,264, 3 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2.
- chr14:21,918,188–22,507,723, 80 genes, copy number 7–10 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.
- chr14:63,122,888–63,736,505, 21 genes, copy number 7: AL137191.1, PARP1P2, RHOJ, AL049871.1, GPHB5, PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P.
- chr14:63,762,013–63,848,362, 3 genes, copy number 7: AL161670.1, RPS28P1, Y_RNA.
- chr15:21,307,749–21,951,323, 30 genes, copy number 12–32: RNU6-1235P, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.

Autosomal genes at a single copy (total copy number 1): 680. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
